Somatic mutation profile of tumor specimen 0E18HU from CCDI case PBCVVE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E18HU: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f54c567-072d-4dac-adb4-01b15d2c3d64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E18I3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31d9050e-2c04-4ecb-a9ab-cdd34d318eb5

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 5, Intron 2, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL16 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs369598646; called by muse, mutect2
- ATP2B3 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 41/507 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1160033001, COSV99685224; called by muse, mutect2
- CPXCR1 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs772550904; called by muse, mutect2, varscan2
- MAPK15 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 74/366 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs550675679, COSV62027318; called by muse, mutect2, varscan2
- MYH1 | c.503C>G p.T168S | Missense Mutation (SNP) | VAF 32/786 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV56848906; called by muse, mutect2
- PCDHA9 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as rs782029014; called by muse, mutect2, varscan2
- SMCR8 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 92/641 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100329243; called by muse, varscan2
- TGFB3 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 23/510 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as COSV99472588; called by muse, mutect2
- TPRG1 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 67/513 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1385628341; called by muse, mutect2, varscan2
- ADA2 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.047); called by muse, mutect2
- ADAM33 | c.333+6A>G | Splice Region (SNP) | VAF 20/433 reads (5%) | called by muse, mutect2
- AFDN | c.2894G>T p.C965F | Missense Mutation (SNP) | VAF 67/415 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C5 | c.4391T>A p.L1464Q | Missense Mutation (SNP) | VAF 72/361 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- CA3 | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.11); called by muse, varscan2
- CAST | c.812C>A p.A271D (on ENST00000341926; = p.A354D on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- CELSR3 | c.3466C>A p.H1156N | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- CYSLTR2 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DNAH10 | c.4700A>T p.K1567M (on ENST00000409039; = p.K1506M on NM_207437.3) | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, varscan2
- EFHD1 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2
- FHL2 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 18/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPER1 | c.220T>G p.F74V | Missense Mutation (SNP) | VAF 31/435 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- INCENP | c.2200G>T p.E734* (on ENST00000394818 / NM_001040694.2; = p.E730* on NM_020238.3) | Nonsense Mutation (SNP) | VAF 39/369 reads (11%) | called by muse, mutect2, varscan2
- LOXL3 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 32/732 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.091); called by muse, mutect2
- MYH4 | c.3967C>A p.L1323I | Missense Mutation (SNP) | VAF 20/597 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2
- NUP214 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 27/589 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2
- PCDHGA1 | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 62/596 reads (10%) | called by muse, mutect2, varscan2
- RGL3 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- TFB1M | c.1002A>C p.E334D | Missense Mutation (SNP) | VAF 99/537 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR8 | c.1315C>A p.Q439K (on ENST00000218032 / NM_138636.5; = p.Q457K on NM_016610.4) | Missense Mutation (SNP) | VAF 33/548 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.077); called by muse, mutect2
- TMF1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 15/462 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); called by muse, mutect2
- TRIP10 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- USP32 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 240/2565 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF236 | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 22/586 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ATP1A2 | c.27C>T p.Y9= | Silent (SNP) | VAF 20/458 reads (4%) | called by muse, mutect2
- CCDC107 | c.81C>A p.A27= | Silent (SNP) | VAF 25/445 reads (6%) | called by muse, mutect2
- CTSA | c.906C>A p.G302= | Silent (SNP) | VAF 32/696 reads (5%) | called by muse, mutect2
- FBXO27 | c.831C>A p.I277= | Silent (SNP) | VAF 68/434 reads (16%) | catalogued as rs1020876736, COSV53071954; called by muse, varscan2
- SMAD7 | c.414G>T p.P138= | Silent (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
- EIF2B5 | c.1894-92G>C | Intron (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- H4C7 | c.-7G>A | 5'UTR (SNP) | VAF 40/342 reads (12%) | called by muse, varscan2
- PDE11A | c.1071+15866C>A | Intron (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- PLCXD1 | c.*71G>T | 3'UTR (SNP) | VAF 23/457 reads (5%) | called by muse, mutect2
